Somatic mutation profile of tumor specimen C3N-01380-01 (aliquot CPT0088260010) from CPTAC case C3N-01380, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.0 years (24,117 days).
Specimen C3N-01380-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 970ffef4-0d21-4d89-baf2-add8d5b4f351.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01380-31 (Blood Derived Normal), aliquot CPT0088300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b0d25f4-084a-4050-bf37-19bb76104968

The open-access MAF lists 35 somatic variants for this specimen: 16 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 13, Intron 2, Splice Site 1, RNA 1, 3'UTR 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 124/771 reads (16%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A1BG | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 34/409 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as COSV99568648; called by muse, mutect2
- ADAMTS12 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs777630888, COSV100711434, COSV61275688; called by muse, mutect2, varscan2
- ARHGAP33 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 28/403 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1252796957; called by muse, mutect2
- B3GNT8 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 47/445 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs549435727; called by muse, mutect2, varscan2
- GFRA1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1005537154, COSV100815894, COSV62602441; called by muse, mutect2
- LRRC7 | c.2394G>A p.M798I (on ENST00000651989 / NM_001370785.2; = p.M765I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs568596228; called by muse, mutect2
- MROH2A | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1335912161; called by muse, mutect2
- MROH2A | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs930450394; called by muse, mutect2
- PDZRN3 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 47/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1240349665; called by muse, mutect2, varscan2
- TNFRSF8 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 50/463 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs764000451, COSV99821474; called by muse, mutect2
- CAMK1D | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.804); called by muse, mutect2
- GRM3 | c.1247C>G p.T416S | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2
- MCM9 | c.2360G>A p.S787N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D19 | c.1085-2_1087delinsTTTTTT p.X362_splice | Splice Site (INS) | VAF 3/32 reads (9%) | called by pindel, varscan2*
- TMEM63B | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.61); called by muse, mutect2
- AS3MT | c.621G>T p.L207= | Silent (SNP) | VAF 10/197 reads (5%) | called by muse, mutect2
- ENTR1 | c.1290C>T p.D430= (on ENST00000357365 / NM_001039707.2; = p.D407= on NM_006643.4) | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as rs372063103; called by muse, mutect2, varscan2
- FKBPL | c.402A>G p.G134= | Silent (SNP) | VAF 25/462 reads (5%) | called by muse, mutect2
- FMO1 | c.1383G>A p.L461= | Silent (SNP) | VAF 24/239 reads (10%) | called by muse, mutect2, varscan2
- HOXD1 | c.165C>A p.P55= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- OR52N5 | c.579A>T p.V193= | Silent (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- PASD1 | c.675C>T p.Y225= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs773316022, COSV100949570; called by muse, varscan2
- PCDHA3 | c.429C>T p.S143= | Silent (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- PCDHA5 | c.1446C>T p.D482= | Silent (SNP) | VAF 90/930 reads (10%) | catalogued as rs1328701255, COSV65349916; called by muse, mutect2
- SETDB1 | c.1941G>A p.E647= | Silent (SNP) | VAF 53/362 reads (15%) | called by muse, mutect2, varscan2
- SLC29A2 | c.399C>T p.S133= | Silent (SNP) | VAF 36/396 reads (9%) | catalogued as rs145126639; called by muse, mutect2
- ZNF140 | c.639A>T p.G213= | Silent (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- ZNF646 | c.5181G>A p.T1727= | Silent (SNP) | VAF 13/309 reads (4%) | catalogued as rs1258184636, COSV54922928; called by muse, mutect2
- AC005865.1 | chr12:3298178 G>A | 3'Flank (SNP) | VAF 30/414 reads (7%) | catalogued as rs762362364; called by muse, mutect2
- OR5E1P | n.460C>T | RNA (SNP) | VAF 17/267 reads (6%) | catalogued as rs183371732; called by muse, mutect2
- PKP3 | c.2359-75A>C | Intron (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- SUN2 | c.1664-24C>T | Intron (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- TMEM135 | c.*6178T>C | 3'UTR (SNP) | VAF 17/111 reads (15%) | catalogued as rs1402225442; called by muse, mutect2
- TRMT61A | c.-83G>A | 5'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
